Gene-level copy-number profile of tumor specimen TCGA-BA-A4II-01A from TCGA case TCGA-BA-A4II, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 46.6 years (17,011 days).
Specimen TCGA-BA-A4II-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.fd1ff6bd-b9a5-4c27-9004-831d778e94e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-A4II-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5681b76f-332d-41e1-ade8-a5d1a06ec4e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 16,326; copy number 2: 38,375; copy number 3: 3,560; copy number 4: 1,023; copy number 5: 231; copy number 6: 42; copy number 8: 58; copy number 9: 67; copy number 10: 16; copy number 15: 28; copy number 17: 14; copy number 18: 2; copy number 22: 25; copy number 25: 29; copy number 28: 1; copy number 37: 6; copy number 50: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-A4II-01A-11D-A25X-01): tumor purity 0.31, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 10 genes (within-gene range 0–1): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 523 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,272,932–178,844,429, 2 genes, copy number 5 (within-gene range 4–5): KCNMB2, AC117457.1.
- chr3:178,526,505–183,116,075, 87 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr3:188,153,284–188,890,671, 1 gene, copy number 10 (within-gene range 2–10): LPP.
- chr3:188,562,238–189,325,304, 6 genes, copy number 10 (within-gene range 2–10): LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2.
- chr3:189,829,922–189,830,009, 1 gene, copy number 5: MIR944.
- chr3:189,969,030–189,969,861, 1 gene, copy number 5: MTAPP2.
- chr7:52,493,152–57,837,046, 173 genes, copy number 5–25 (broad region; genes not listed).
- chr8:35,672,195–35,707,734, 1 gene, copy number 28: AC105230.1.
- chr8:41,490,396–42,051,994, 18 genes, copy number 5: GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1.
- chr8:127,072,694–127,742,951, 12 genes, copy number 18–50: CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr11:58,491,773–59,457,991, 42 genes, copy number 6: AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4, GLYATL1B, FAM111B, FAM111A-DT, AP001258.1, FAM111A, DTX4, MPEG1, RN7SL42P, WARS1P1, SLC25A47P1, AP002358.1, AP002358.2, RN7SL435P, OR5AN2P, OR5BR1P, OR5AN1, OR5BB1P, OR5A2, OR5A1, OR4D6.
- chr11:66,614,964–71,252,577, 160 genes, copy number 5–22 (broad region; genes not listed).
- chr17:73,334,384–74,355,820, 19 genes, copy number 5 (within-gene range 1–5): SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1, AC137735.3, AC137735.2, LINC02074, RPL38, MGC16275, TTYH2, AC100786.1, DNAI2, AC103809.1, KIF19.

Autosomal genes at a single copy (total copy number 1): 13,905. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
